Gene-level copy-number profile of tumor specimen TCGA-DX-A8BM-01A from TCGA case TCGA-DX-A8BM, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 60.6 years (22,152 days).
Specimen TCGA-DX-A8BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.fe565711-ae28-4680-95ec-cd0b2c0bb754.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BM-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 841 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9da6e6b-25ce-4547-9ff6-4ba09e4994de

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 3,041; copy number 2: 14,784; copy number 3: 25,171; copy number 4: 12,269; copy number 5: 2,999; copy number 6: 814; copy number 7: 439; copy number 8: 228.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BM-01A-11D-A416-01): tumor purity 0.75, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–209,892, 2 genes: FAM110C, AC079779.1.
- chr10:44,712–689,668, 10 genes (within-gene range 0–2): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1.
- chr10:1,957,589–2,728,267, 13 genes: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1.
- chr15:67,521,131–67,834,582, 5 genes: C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1.
- chr15:67,834,310–67,840,045, 2 genes: AC009292.1, RNU6-1.
- chr17:7,661,779–7,833,744, 5 genes (within-gene range 0–1): TP53, WRAP53, EFNB3, DNAH2, RPL29P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 651 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:210,477,682–210,679,107, 2 genes, copy number 7 (within-gene range 5–7): CPS1, CPS1-IT1.
- chr2:214,241,676–214,684,246, 1 gene, copy number 7 (within-gene range 6–7): AC068051.1.
- chr2:214,411,054–214,809,683, 4 genes, copy number 7: VWC2L, VWC2L-IT1, ENSAP3, BARD1.
- chr2:215,178,791–215,349,773, 3 genes, copy number 7 (within-gene range 5–7): AC092844.1, LINC02862, ATIC.
- chr5:3,177,835–6,030,841, 34 genes, copy number 7: LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1, AC010266.2, AC010266.1.
- chr5:21,750,673–22,853,344, 1 gene, copy number 7 (within-gene range 5–7): CDH12.
- chr5:22,139,247–23,528,093, 12 genes, copy number 7: AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr17:27,928,924–28,335,489, 22 genes, copy number 7: LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7, PYY2, ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5, AC061975.3, KRT18P55, TMEM97, IFT20.
- chr17:33,680,577–34,639,318, 26 genes, copy number 7 (within-gene range 2–7): AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E.
- chr19:4,969,113–15,233,435, 546 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,031. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
